Somatic mutation profile of tumor specimen TCGA-DW-7834-01A (aliquot TCGA-DW-7834-01A-11D-2136-08) from TCGA case TCGA-DW-7834, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 53.8 years (19,660 days).
Specimen TCGA-DW-7834-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c0a9f16-4051-4242-a288-3d66132920f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DW-7834-10A (Blood Derived Normal), aliquot TCGA-DW-7834-10A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a1339e1-53b2-47ce-93a7-1296f6851905

The open-access MAF lists 60 somatic variants for this specimen: 48 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 11, Nonsense Mutation 2, Frame Shift Ins 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRB3 | c.2542C>T p.H848Y | Missense Mutation (SNP) | VAF 63/206 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV53235422; called by muse, mutect2, varscan2
- AEBP1 | c.2269G>C p.V757L | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV56255621; called by muse, mutect2, varscan2
- AP3D1 | c.81C>G p.N27K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV61424691; called by muse, mutect2, varscan2
- ARID1A | c.2234G>A p.S745N | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV61372343, COSV61392226; called by muse, mutect2
- CFAP57 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as COSV65263684; called by muse, mutect2, varscan2
- DDX60 | c.3842G>A p.R1281K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.284); catalogued as COSV67095226; called by muse, mutect2, varscan2
- DEDD | c.875T>G p.L292R | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63501219; called by muse, mutect2, varscan2
- DNAH8 | c.544A>G p.M182V | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.229); catalogued as COSV59426967; called by muse, mutect2, varscan2
- EFTUD2 | c.1094C>T p.S365F | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV68182328; called by muse, mutect2, varscan2
- FCHO2 | c.2375A>G p.Y792C | Missense Mutation (SNP) | VAF 54/205 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1297710349, COSV59270067; called by muse, mutect2, varscan2
- GPR18 | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV100540515, COSV61620972, COSV61621105; called by muse, mutect2, varscan2
- IFIH1 | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55124768; called by muse, mutect2, varscan2
- IL10RA | c.228C>A p.S76R | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV57139812; called by muse, mutect2, varscan2
- KATNIP | c.1430T>C p.I477T | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV55174050; called by muse, mutect2, varscan2
- KIF20B | c.3740A>C p.E1247A (on ENST00000371728 / NM_001284259.2; = p.E1207A on NM_016195.4) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV53302771; called by muse, mutect2, varscan2
- LPIN1 | c.602T>C p.L201P | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV56762694; called by muse, mutect2, varscan2
- LUC7L2 | c.1125T>A p.N375K | Missense Mutation (SNP) | VAF 94/184 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.109); catalogued as COSV54923765; called by muse, mutect2, varscan2
- MAP7D3 | c.947A>G p.N316S | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as rs1205698999, COSV60170121; called by muse, mutect2, varscan2
- MEGF8 | c.4873C>G p.L1625V (on ENST00000251268 / NM_001271938.2; = p.L1558V on NM_001410.3) | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV52076001; called by muse, mutect2, varscan2
- MTMR14 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56003368; called by muse, mutect2
- MYOM3 | c.868C>A p.L290M | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV58390059; called by muse, varscan2
- NAALADL1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1237821709, COSV100368302; called by muse, mutect2, varscan2
- NABP1 | c.65A>C p.N22T | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV57138437; called by muse, mutect2, varscan2
- NUBP2 | c.73G>C p.G25R | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51904776; called by muse, mutect2, varscan2
- NUGGC | c.1853G>C p.G618A | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV58432509; called by muse, mutect2, varscan2
- OGDH | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56045900; called by muse, mutect2, varscan2
- PCDH15 | c.4595G>A p.R1532Q (on ENST00000644397 / NM_001354429.2; = p.R1481Q on NM_001142769.3) | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs749774874, COSV64674378, COSV64686357; called by muse, mutect2, varscan2
- PDZD2 | c.3413G>T p.S1138I | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs1421179137, COSV56851514; called by muse, mutect2, varscan2
- PEF1 | c.193G>T p.G65* | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV65483357; called by muse, mutect2, varscan2
- PLXNA2 | c.4148G>A p.R1383Q | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs758747529, COSV65437865; called by muse, mutect2, varscan2
- PPP1R36 | c.279T>A p.D93E | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.86); PolyPhen benign (0.018); catalogued as COSV53901014; called by muse, varscan2
- PRSS55 | c.656G>A p.W219* | Nonsense Mutation (SNP) | VAF 31/87 reads (36%) | catalogued as COSV60807768; called by muse, mutect2, varscan2
- PSMC4 | c.321A>G p.T107= | Splice Region (SNP) | VAF 11/42 reads (26%) | catalogued as COSV50094298; called by muse, mutect2, varscan2
- PTGER1 | c.940C>A p.L314M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52874467; called by muse, mutect2
- PTPRJ | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV69249945; called by muse, mutect2, varscan2
- PZP | c.204A>T p.E68D | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.027); catalogued as COSV54354979; called by muse, mutect2, varscan2
- RFX6 | c.1626T>A p.N542K | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.724); catalogued as COSV60583554; called by muse, mutect2, varscan2
- RGS1 | c.283G>C p.G95R | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66504620; called by muse, mutect2, varscan2
- SELENOP | c.268A>T p.N90Y | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62791738; called by muse, mutect2, varscan2
- SF3B1 | c.800C>A p.T267N | Missense Mutation (SNP) | VAF 74/211 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.544); catalogued as COSV59207506; called by muse, mutect2, varscan2
- SLC7A8 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV57553089; called by muse, mutect2, varscan2
- THSD7B | c.1534A>G p.T512A | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV55657386; called by muse, mutect2, varscan2
- VARS2 | c.1385T>C p.L462P | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58911347; called by muse, mutect2, varscan2
- VCAN | c.97A>T p.R33W | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54097563; called by muse, varscan2
- VSTM2A | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56492364; called by muse, mutect2, varscan2
- WWC2 | c.722A>C p.D241A | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV66712444; called by muse, mutect2, varscan2
- ZNF76 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.183); catalogued as rs1562133897, COSV57353184; called by muse, mutect2, varscan2
- UBR2 | c.2097+2_2097+6dup | Frame Shift Ins (INS) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- DNAJC22 | c.711T>C p.L237= | Silent (SNP) | VAF 82/259 reads (32%) | catalogued as COSV67711437; called by muse, mutect2, varscan2
- DSEL | c.384T>C p.N128= | Silent (SNP) | VAF 38/123 reads (31%) | catalogued as COSV59489586; called by muse, mutect2, varscan2
- EIF2S1 | c.606T>C p.Y202= | Silent (SNP) | VAF 56/154 reads (36%) | catalogued as COSV56451822; called by muse, mutect2, varscan2
- NCAM2 | c.411A>T p.R137= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV53058125; called by muse, varscan2
- NRIP1 | c.2844T>C p.D948= | Silent (SNP) | VAF 40/143 reads (28%) | catalogued as COSV59655292; called by muse, mutect2, varscan2
- NUP133 | c.882C>A p.I294= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV54568464; called by muse, mutect2, varscan2
- PMEPA1 | c.357G>A p.L119= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV55691826; called by muse, mutect2
- RHBDD3 | c.621G>T p.G207= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV53322805; called by muse, mutect2, varscan2
- TOP3A | c.228T>C p.H76= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV58175079; called by muse, mutect2, varscan2
- TRIM8 | c.507C>T p.Y169= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV56659633; called by muse, mutect2, varscan2
- WNT3 | c.768G>A p.V256= | Silent (SNP) | VAF 75/165 reads (45%) | catalogued as COSV56644073; called by muse, mutect2, varscan2
- SON | c.6657+301A>G | Intron (SNP) | VAF 53/169 reads (31%) | catalogued as rs1365971228, COSV99280237; called by muse, mutect2, varscan2
